Gene-level copy-number profile of tumor specimen ALCH-AEPS-TTP1-A from ALCHEMIST case ALCH-AEPS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.8 years (24,770 days).
Specimen ALCH-AEPS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bd8d861c-5bc9-4911-867a-f290bcc58e0d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEPS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,256 have no estimate.
https://portal.gdc.cancer.gov/files/bca9d31d-51a3-467c-a8e9-f65c93037c78

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 18; copy number 2: 254; copy number 3: 893; copy number 4: 19,199; copy number 5: 8,018; copy number 6: 15,734; copy number 7: 6,715; copy number 8: 3,620; copy number 9: 2,362; copy number 10: 785; copy number 11: 90; copy number 12: 165; copy number 13: 44; copy number 14: 9; copy number 15: 210; copy number 16: 42; copy number 17: 138.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,341,669–22,455,740, 65 genes (broad region; genes not listed).
- chr9:112,878,920–112,890,876, 2 genes (within-gene range 0–4): SLC46A2, AL139041.1.
- chr10:87,225,448–87,236,908, 1 gene (within-gene range 0–3): NUTM2A.
- chr11:1,223,066–1,262,172, 3 genes: MUC5B, MUC5B-AS1, MIR6744.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,429 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,991,134–12,796,628, 155 genes, copy number 10–16 (broad region; genes not listed).
- chr1:20,360,579–41,383,590, 649 genes, copy number 10–17 (broad region; genes not listed).
- chr1:143,419,625–157,949,071, 649 genes, copy number 9 (broad region; genes not listed).
- chr1:159,535,078–161,470,523, 104 genes, copy number 9 (broad region; genes not listed).
- chr2:203,634,577–203,636,016, 1 gene, copy number 12: AC125238.2.
- chr4:49,096–540,200, 22 genes, copy number 9: BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732, AC079140.6, AC079140.4, ZNF141, AC079140.1, AC079140.2, MIR571, AC092574.2, ZNF519P4, AC092574.1, ABCA11P, ZNF721, PIGG.
- chr4:150,264,435–151,325,605, 12 genes, copy number 9 (within-gene range 8–9): LRBA, AC092612.1, AC110813.1, MAB21L2, ZBTB8OSP1, RNA5SP168, AK4P6, RPS3A, SNORD73B, SH3D19, SNORD73A, AC095055.1.
- chr5:31,595,565–33,298,066, 39 genes, copy number 9: RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160.
- chr9:61,190,003–61,453,030, 7 genes, copy number 11: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:64,462,819–64,466,498, 2 genes, copy number 9: CR769776.2, CYP4F25P.
- chr12:26,905,181–30,879,268, 71 genes, copy number 10 (broad region; genes not listed).
- chr12:40,692,439–44,921,848, 53 genes, copy number 9–17: CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, NELL2, Y_RNA.
- chr12:66,950,754–70,637,440, 82 genes, copy number 10–16 (broad region; genes not listed).
- chr12:77,775,783–77,783,576, 1 gene, copy number 15: AC138331.1.
- chr12:89,010,681–89,309,566, 1 gene, copy number 14 (within-gene range 4–14): LINC02458.
- chr12:89,282,223–89,526,047, 8 genes, copy number 14 (within-gene range 4–14): RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B.
- chr14:37,171,888–38,041,442, 11 genes, copy number 9 (within-gene range 6–9): SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517.
- chr16:11,555–523,011, 40 genes, copy number 9: DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25, RHBDF1, Z69720.2, MPG, NPRL3, Z69720.1, Z69666.1, HBZ, HBM, HBZP1, HBAP1, HBA2, HBA1, Y_RNA, HBQ1, Z69706.1, LUC7L, Z69890.1, FAM234A, RGS11, Z69667.1, ARHGDIG, PDIA2, AXIN1, MRPL28, PGAP6, Z97634.1, NME4, DECR2, AL023881.1, RAB11FIP3, Y_RNA, AL049542.1.
- chr16:1,706,183–1,770,351, 5 genes, copy number 11 (within-gene range 7–11): MAPK8IP3, AL031710.2, AL031710.1, MIR3177, AL031717.1.
- chr16:2,275,881–4,273,075, 132 genes, copy number 10 (broad region; genes not listed).
- chr16:4,425,805–19,886,167, 377 genes, copy number 9–11 (broad region; genes not listed).
- chr17:18,835,707–18,931,287, 5 genes, copy number 9: AC107982.1, PRPSAP2, RN7SL627P, AC107982.2, AC090286.3.
- chr21:44,217,014–44,244,993, 3 genes, copy number 16: ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
